Somatic mutation profile of tumor specimen TCGA-19-1788-01A (aliquot TCGA-19-1788-01A-01W-0643-08) from TCGA case TCGA-19-1788, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.2 years (14,301 days).
Specimen TCGA-19-1788-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f9f11a5-2fc4-49f6-a72b-a37e67de1473.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1788-10A (Blood Derived Normal), aliquot TCGA-19-1788-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b732dc5-7957-4828-968d-028f80b8adfd

The open-access MAF lists 78 somatic variants for this specimen: 61 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 48, Silent 17, Frame Shift Del 6, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- MAX | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 58/332 reads (17%) | catalogued as rs387906651, CM115472, COSV52415510; ClinVar: risk factor / pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1278453387, COSV99419047; called by muse, mutect2
- ABHD10 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99844994; called by muse, mutect2
- ACOX3 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100711929; called by muse, mutect2, varscan2
- ADAM15 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 49/548 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1165112093, COSV99664914; called by muse, mutect2
- AFMID | c.751T>A p.F251I | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100014907; called by muse, mutect2, varscan2
- ARHGDIB | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 73/333 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV57456200; called by muse, mutect2, varscan2
- ATMIN | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.514); catalogued as rs751306740, COSV55145672, COSV55147036; called by muse, varscan2
- ATP9B | c.1823G>T p.R608M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56956426; called by muse, mutect2
- BMPR1B | c.76dup p.R26Pfs*8 | Frame Shift Ins (INS) | VAF 10/89 reads (11%) | catalogued as rs1271170297; called by mutect2, varscan2
- C11orf58 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV99930230; called by muse, mutect2, varscan2
- C6orf136 | c.518C>T p.S173F (on ENST00000376473 / NM_001109938.3; = p.S39F on NM_145029.4) | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99527866; called by muse, mutect2, varscan2
- CBLN2 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as rs1193984103, COSV54053560; called by muse, mutect2, varscan2
- CENPF | c.2695G>T p.V899F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as COSV100871651; called by muse, mutect2, varscan2
- CERK | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 30/1239 reads (2%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs889300720, COSV53451769; called by muse, mutect2
- CNN3 | c.863C>A p.T288K | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.245); catalogued as COSV99598038; called by muse, mutect2
- CNTD1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100162083; called by muse, varscan2
- CSF2RB | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs770782845, COSV53261563; called by muse, mutect2, varscan2
- DCC | c.1574-1G>T p.X525_splice | Splice Site (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100499309; called by muse, mutect2
- EDC4 | c.1154C>A p.T385K | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100739062; called by muse, mutect2
- EML4 | c.1913G>T p.C638F | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100580822; called by mutect2, varscan2
- EPS8 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs147224631; called by muse, mutect2
- GART | c.2754G>T p.L918F | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101111368; called by muse, mutect2
- HSF1 | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs782740115; called by muse, mutect2, varscan2
- IL5RA | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99842861; called by muse, mutect2
- ITPR2 | c.2481G>A p.M827I | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT tolerated (0.4); PolyPhen benign (0.191); catalogued as COSV101189936; called by muse, mutect2, varscan2
- LARP4B | c.974G>T p.R325I | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100295221; called by muse, mutect2
- LMNTD1 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV99279646; called by muse, mutect2
- LPAR3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.996); catalogued as rs544005031, COSV101004652; called by muse, mutect2, varscan2
- LRRC19 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV101195784; called by muse, varscan2
- MCC | c.1796G>T p.S599I | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as COSV100202439; called by muse, mutect2, varscan2
- MFAP1 | c.1023T>A p.Y341* | Nonsense Mutation (SNP) | VAF 125/568 reads (22%) | catalogued as COSV99979820; called by mutect2, varscan2
- MRPL44 | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99285184; called by muse, mutect2
- NPHP1 | c.1682G>T p.R561I (on ENST00000393272 / NM_207181.4; = p.R562I on NM_000272.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100337874, COSV57206612; called by muse, mutect2, varscan2
- NVL | c.2509T>C p.S837P | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99894082; called by muse, mutect2, varscan2
- OR4X2 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 129/389 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1475634027, COSV100183214; called by muse, mutect2, varscan2
- PCDH8 | c.2857G>T p.A953S | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.056); catalogued as COSV100131084, COSV100131636; called by muse, mutect2
- PDLIM1 | c.794C>A p.T265N | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV100267740; called by muse, mutect2, varscan2
- PDZRN4 | c.3079C>A p.H1027N (on ENST00000402685 / NM_001164595.2; = p.H769N on NM_013377.4) | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100114206, COSV54207001; called by muse, mutect2
- PHF3 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV100013187; called by muse, mutect2
- PJA2 | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.292); catalogued as COSV100754385; called by muse, mutect2, varscan2
- RPS6KB1 | c.1228-2A>G p.X410_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99847397, COSV99847441; called by muse, mutect2, varscan2
- RTEL1 | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV100542059; called by muse, mutect2, varscan2
- SLC6A20 | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV100653636, COSV62071101; called by muse, mutect2
- STAG1 | c.2334G>C p.Q778H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs762160605, COSV52610194, COSV99365135; called by muse, mutect2, varscan2
- TASOR2 | c.3659C>A p.S1220* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | catalogued as COSV100050970; called by muse, mutect2
- TTC21B | c.2489A>G p.D830G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV99692162; called by muse, mutect2
- ZNF10 | c.1651G>T p.G551W | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99939935; called by muse, mutect2
- ZNF304 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs751628661, COSV99988869; called by mutect2, varscan2
- ZSCAN2 | c.1479G>T p.Q493H | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV100306875; called by muse, mutect2
- ALDH1L2 | c.2296_2315del p.D766* | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- ATRX | c.2093del p.K698Rfs*11 | Frame Shift Del (DEL) | VAF 66/173 reads (38%) | called by mutect2, pindel, varscan2
- JCAD | c.2535_2537dup p.E847dup | In Frame Ins (INS) | VAF 5/38 reads (13%) | called by mutect2*, pindel
- KCNK5 | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0100 | c.6082T>C p.F2028L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- NRCAM | c.907del p.Y303Tfs*39 (on ENST00000379028 / NM_001371124.1; = p.Y297Tfs*39 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/135 reads (20%) | called by mutect2, pindel, varscan2
- SLC2A12 | c.827G>C p.R276P | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TP53 | c.759_762del p.I254Sfs*90 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | called by mutect2, pindel, varscan2
- TP53 | c.351del p.T118Qfs*5 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- UPF1 | c.1475del p.T492Mfs*7 (on ENST00000599848 / NM_001297549.2; = p.T481Mfs*7 on NM_002911.4) | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- ABCC12 | c.207G>T p.R69= | Silent (SNP) | VAF 52/376 reads (14%) | called by mutect2, varscan2
- ATP6V1H | c.540C>T p.S180= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs373947892; called by muse, mutect2, varscan2
- CHRNB2 | c.585C>T p.D195= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs764809084, COSV100872588; called by muse, mutect2, varscan2
- EBNA1BP2 | c.339G>A p.Q113= | Silent (SNP) | VAF 46/541 reads (9%) | catalogued as COSV99355906; called by muse, mutect2
- FNDC3B | c.606C>T p.R202= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100393991; called by muse, mutect2, varscan2
- GEMIN2 | c.471G>A p.G157= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as COSV51629241; called by muse, mutect2
- HAP1 | c.1797G>A p.L599= (on ENST00000310778 / NM_001367460.1; = p.L547= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1555588323, COSV100169613; called by muse, varscan2
- IMPDH2 | c.63G>A p.Q21= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV58707882; called by muse, mutect2, varscan2
- KDM7A | c.1029A>G p.G343= | Silent (SNP) | VAF 27/274 reads (10%) | catalogued as rs368371283; called by muse, mutect2
- KIAA0232 | c.141C>A p.L47= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100300626; called by muse, mutect2
- OAS2 | c.1419C>A p.V473= | Silent (SNP) | VAF 32/293 reads (11%) | catalogued as COSV100660100; called by muse, varscan2
- PPFIA3 | c.3162C>A p.G1054= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99417816; called by muse, mutect2
- SALL2 | c.2013G>A p.R671= | Silent (SNP) | VAF 52/93 reads (56%) | catalogued as COSV100444281; called by muse, mutect2, varscan2
- TNC | c.2511C>T p.Y837= | Silent (SNP) | VAF 62/261 reads (24%) | catalogued as rs146641282; called by muse, varscan2
- ZFYVE9 | c.1185A>G p.E395= | Silent (SNP) | VAF 122/197 reads (62%) | catalogued as COSV99819792; called by muse, mutect2, varscan2
- ZMAT5 | c.87G>A p.Q29= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1159824401; called by muse, mutect2
- ZNF74 | c.183C>T p.D61= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as rs779966901, COSV100677454; called by muse, mutect2, varscan2
